Somatic mutation profile of tumor specimen BA2292D (aliquot aq-BA2292D) from BEATAML1.0 case 2056, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.9 years (25,523 days).
Specimen BA2292D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe2bd2e1-0b0b-43b0-a0d1-9554d1ae9693.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2176D (Solid Tissue Normal), aliquot aq-BA2176D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43f6c61e-6032-465f-851f-4252ee07db89

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 72/134 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EIF3D | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53403538, COSV53404251; called by muse, mutect2
- EZH2 | c.2129T>C p.I710T (on ENST00000460911 / NM_001203247.2; = p.I715T on NM_004456.5) | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV57461392; called by muse, varscan2
- CCR4 | c.918del p.L307Wfs*60 | Frame Shift Del (DEL) | VAF 45/109 reads (41%) | called by mutect2, varscan2
- KLHL1 | c.138del p.F46Lfs*20 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- MYO7A | c.1188C>A p.D396E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TENM1 | c.6103G>T p.V2035L | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.569); called by muse, mutect2
- ZNF131 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.87); called by muse, varscan2
- HID1 | c.582C>T p.P194= | Silent (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2, varscan2
- PCDH8 | c.738G>T p.P246= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- XKR4 | c.588C>A p.V196= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- PDE4DIP | c.637-7295dup | Intron (INS) | VAF 37/112 reads (33%) | called by mutect2, pindel, varscan2
